Somatic mutation profile of tumor specimen MMRF_1957_1_BM_CD138pos (aliquot MMRF_1957_1_BM_CD138pos_T1_KBS5U_L06455) from MMRF case MMRF_1957, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.4 years (27,522 days).
Specimen MMRF_1957_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 531a76ab-07ed-4667-a6af-13a7a4ad95be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1957_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1957_1_PB_Whole_C2_KBS5U_L06488; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35885280-b6d5-4093-9be1-ee6f2a764811

The open-access MAF lists 109 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 26, Silent 18, Intron 13, RNA 4, Nonsense Mutation 4, 5'UTR 3, Splice Site 2, Splice Region 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN2A | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518048, COSV99331861; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.2291A>G p.Y764C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62425086; called by muse, mutect2
- CACNA1E | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768773946, COSV62437200; called by muse, mutect2, varscan2
- CCDC27 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs750795328, COSV99622155; called by muse, mutect2
- CSMD3 | c.4195G>A p.E1399K (on ENST00000297405 / NM_001363185.1; = p.E1295K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV52164500, COSV52288099; called by muse, mutect2, varscan2
- CTR9 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV100797540; called by muse, mutect2, varscan2
- HUNK | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780570018, COSV54231053; called by muse, mutect2, varscan2
- IGHJ6 | c.19_20del p.M7Gfs*? | Frame Shift Del (DEL) | VAF 28/41 reads (68%) | catalogued as rs782382166; called by mutect2, varscan2
- IGHV2-70 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs755372451; called by muse, varscan2
- ITPK1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs369752282; called by muse, mutect2, varscan2
- LRP1B | c.12462T>G p.N4154K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs773189120, COSV67188364; called by muse, mutect2, varscan2
- LUZP2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 15/416 reads (4%) | catalogued as rs1326382090; called by muse, mutect2
- NID2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs994526138; called by muse, mutect2, varscan2
- PLA2G4F | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs770482481, COSV51828168; called by muse, mutect2, varscan2
- PRR23C | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs1457133253; called by muse, mutect2
- SCARA3 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100106474; called by muse, mutect2, varscan2
- SCEL | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as rs1334262237; called by muse, mutect2, varscan2
- SP2 | c.1505G>C p.R502P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65064242; called by muse, mutect2, varscan2
- TSHZ3 | c.1613A>C p.Q538P | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99551997; called by muse, mutect2, varscan2
- UBR5 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs771189541, COSV55282005; called by muse, mutect2, varscan2
- ADGRL3 | c.4701G>C p.E1567D (on ENST00000506720 / NM_001322402.2; = p.E1456D on NM_015236.6) | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ASCC3 | c.3349G>T p.D1117Y | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATM | c.8610T>G p.D2870E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf94 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CSNK1A1L | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSTF2 | c.332T>G p.I111S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DDAH2 | c.398-4T>G | Splice Region (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- DDI1 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP2 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- FRAS1 | c.6998T>C p.F2333S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2
- HIP1R | c.2890+1G>T p.X964_splice | Splice Site (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- IFT88 | c.962C>G p.T321S (on ENST00000319980 / NM_001318493.2; = p.T312S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGHMBP2 | c.1927C>A p.L643I | Missense Mutation (SNP) | VAF 43/1304 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2
- LAMA3 | c.3430C>T p.Q1144* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- MYH8 | c.2705C>A p.A902D | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFIA | c.27+1G>A p.X9_splice | Splice Site (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- OR5J2 | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- OR5J2 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PCDHGA4 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRC1 | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RREB1 | c.3922del p.D1308Mfs*101 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, varscan2
- SDAD1 | c.1664A>T p.D555V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SF3B1 | c.3266+8T>A | Splice Region (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- ZNF208 | c.342A>T p.K114N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- AHNAK2 | c.15261C>A p.L5087= | Silent (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- BLM | c.345G>A p.P115= | Silent (SNP) | VAF 112/284 reads (39%) | catalogued as rs374578971; called by muse, mutect2, varscan2
- CCDC158 | c.3165G>A p.Q1055= | Silent (SNP) | VAF 51/131 reads (39%) | called by muse, mutect2, varscan2
- CMTR1 | c.576G>A p.G192= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as rs760675975; called by muse, mutect2, varscan2
- GAS2L3 | c.138T>A p.T46= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- GDPD4 | c.345G>T p.V115= | Silent (SNP) | VAF 30/651 reads (5%) | called by muse, mutect2
- GPT2 | c.547C>T p.L183= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- IGHV2-70 | c.78T>G p.S26= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs370260778; called by muse, varscan2
- KCNMA1 | c.951C>T p.F317= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- KDM3B | c.4371G>T p.V1457= | Silent (SNP) | VAF 46/138 reads (33%) | called by muse, mutect2, varscan2
- LINGO2 | c.378G>A p.T126= | Silent (SNP) | VAF 66/171 reads (39%) | catalogued as rs745910156, COSV58060263; called by muse, mutect2, varscan2
- MYO1H | c.2412C>T p.V804= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MYOT | c.990A>C p.G330= | Silent (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- NR3C1 | c.1861C>T p.L621= | Silent (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- NR3C1 | c.1860G>C p.L620= | Silent (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- POMGNT2 | c.1164C>T p.L388= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs141218976; ClinVar: likely benign; called by muse, mutect2, varscan2
- VCP | c.1152T>C p.H384= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- WDR25 | c.636C>T p.Y212= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs758455079; called by muse, mutect2, varscan2
- ADGRG6 | c.3422-42C>T | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as rs540550271; called by muse, mutect2, varscan2
- AHI1 | c.3109+6906C>G | Intron (SNP) | VAF 70/168 reads (42%) | called by muse, mutect2, varscan2
- ALG8 | c.95+277T>A | Intron (SNP) | VAF 11/344 reads (3%) | called by muse, mutect2
- AMMECR1L | c.*1108A>G | 3'UTR (SNP) | VAF 45/113 reads (40%) | catalogued as rs1402012445; called by muse, mutect2, varscan2
- ARHGEF4 | c.1337+10C>T | Intron (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- ARL5A | c.*1786C>G | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- ARPC3 | c.380-130A>G | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- ASB2 | c.*48del | 3'UTR (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- B4GALT1 | c.*2443G>A | 3'UTR (SNP) | VAF 35/139 reads (25%) | catalogued as rs1463778315; called by muse, mutect2, varscan2
- BLACE | n.1611C>A | RNA (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- C1orf68 | c.*6C>T | 3'UTR (SNP) | VAF 24/71 reads (34%) | catalogued as rs773547274; called by muse, mutect2, varscan2
- CCDC3 | c.*1630C>T | 3'UTR (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2
- CLTB | c.*90C>T | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- EFCAB10 | c.383+485T>C | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- FAM107A | c.*853G>T | 3'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- GJD2 | c.*357G>C | 3'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- GLRA3 | c.*3348G>A | 3'UTR (SNP) | VAF 6/109 reads (6%) | catalogued as rs1468034770; called by muse, mutect2
- HEXD | c.982+40C>T | Intron (SNP) | VAF 47/113 reads (42%) | catalogued as rs758321746; called by muse, mutect2, varscan2
- INSYN2A | c.*2365C>T | 3'UTR (SNP) | VAF 21/68 reads (31%) | catalogued as rs1478495353, COSV99730375; called by muse, mutect2, varscan2
- KIF21B | chr1:200972417 C>T | 3'Flank (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- KLHL8 | c.*2646G>A | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- KRT77 | c.916-28G>T | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- LARS1 | c.1503+20C>T | Intron (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- LINC01546 | n.853A>G | RNA (SNP) | VAF 25/34 reads (74%) | called by muse, mutect2, varscan2
- LINC02448 | n.190G>A | RNA (SNP) | VAF 46/219 reads (21%) | called by muse, mutect2, varscan2
- MAP9 | c.*3795T>A | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- MARF1 | c.*2044G>C | 3'UTR (SNP) | VAF 17/284 reads (6%) | called by muse, mutect2
- MARF1 | c.*1432G>C | 3'UTR (SNP) | VAF 40/316 reads (13%) | called by muse, varscan2
- MARF1 | c.*1322G>C | 3'UTR (SNP) | VAF 52/320 reads (16%) | called by muse, varscan2
- MCOLN2 | c.*204G>A | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- MEGF6 | c.-5G>A | 5'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- MYO1E | c.-184A>T | 5'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- OGFR | c.240+309C>T | Intron (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- PDCD6IPP2 | n.11G>A | RNA (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PDE10A | c.*151C>T | 3'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PIK3R2 | c.*1157C>T | 3'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RHOT1 | c.*96G>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- RND1 | c.*533C>T | 3'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- SLC25A38 | c.-75C>A | 5'UTR (SNP) | VAF 35/106 reads (33%) | catalogued as rs915915921; called by muse, mutect2, varscan2
- SLPI | c.*175C>A | 3'UTR (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- SNTN | c.*1196G>A | 3'UTR (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- SUGP1 | c.539-139G>T | Intron (SNP) | VAF 10/76 reads (13%) | catalogued as rs770873497; called by muse, mutect2, varscan2
- TANK | c.-49-18202G>A | Intron (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- TIPARP | c.*741C>G | 3'UTR (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- TMED4 | c.535-310A>G | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- TMX4 | c.*4183G>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1527C>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
